CCDI case PBCJJY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ce0f859e-5dde-4aa9-96ab-aad9cb4254b1

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 20.6 years (7,539 days).

Biospecimens (3 samples)
- Sample 0DTD32: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTD36: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTD38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
